Gene-level copy-number profile of tumor specimen TCGA-ER-A2NH-06A from TCGA case TCGA-ER-A2NH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.6 years (18,838 days).
Specimen TCGA-ER-A2NH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ce9edf40-a5d6-419e-8359-630f7dc2a7da.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A2NH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f51a68b5-f997-42ea-8034-07e71bdfd143

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 17,485; copy number 2: 40,122; copy number 3: 2,065; copy number 4: 48; copy number 12: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A2NH-06A-11D-A194-01): tumor purity 0.47, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–23,438,700, 71 genes (broad region; genes not listed).
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–1): PTEN.
- chr10:87,945,502–88,259,372, 4 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,392,790–115,283,763, 19 genes, copy number 12 (within-gene range 4–12): TRIM33, AL035410.1, EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1.

Autosomal genes at a single copy (total copy number 1): 15,099. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
